Somatic mutation profile of tumor specimen TCGA-C4-A0F6-01A (aliquot TCGA-C4-A0F6-01A-11D-A10S-08) from TCGA case TCGA-C4-A0F6, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 82.0 years (29,951 days).
Specimen TCGA-C4-A0F6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22d39c9b-be5c-47c7-8fa5-e510d3b3b73b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C4-A0F6-10A (Blood Derived Normal), aliquot TCGA-C4-A0F6-10A-01D-A10S-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/72009084-d285-46a9-8d23-f9b7bb0d5cd7

The open-access MAF lists 231 somatic variants for this specimen: 175 protein-altering or splice-affecting, 50 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 156, Silent 50, Nonsense Mutation 11, Intron 4, Splice Site 4, In Frame Del 1, 5'UTR 1, Frame Shift Del 1, Splice Region 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRB1 | c.1576C>T p.R526* | Nonsense Mutation (SNP) | VAF 55/110 reads (50%) | catalogued as rs114342808, CM082582, COSV66328638, COSV66328719; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACACB | c.6952G>C p.E2318Q | Missense Mutation (SNP) | VAF 34/209 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as COSV58129008, COSV58140265; called by muse, mutect2, varscan2
- ACD | c.1439G>A p.G480E (on ENST00000620338; = p.G391E on NM_022914.3) | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV54669011; called by muse, mutect2, varscan2
- ADAMTS10 | c.129C>A p.F43L | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.994); catalogued as COSV54356883; called by muse, mutect2, varscan2
- ADAMTS12 | c.2521G>A p.G841R | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377412848, COSV100710612; called by muse, mutect2, varscan2
- ADGRV1 | c.3469T>C p.F1157L | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.729); catalogued as rs932681759, COSV67990457; called by muse, mutect2, varscan2
- ADRA1B | c.730G>C p.E244Q | Missense Mutation (SNP) | VAF 76/102 reads (75%) | SIFT deleterious (0.03); PolyPhen benign (0.411); catalogued as COSV60703080; called by muse, mutect2, varscan2
- AGO1 | c.1756C>G p.Q586E | Missense Mutation (SNP) | VAF 141/187 reads (75%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as COSV64594622; called by muse, mutect2, varscan2
- ANOS1 | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 56/346 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.219); catalogued as rs202023212, COSV52923295; called by muse, mutect2, varscan2
- ARSJ | c.307C>G p.L103V | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59538861; called by muse, mutect2, varscan2
- ATP2A2 | c.213A>G p.I71M | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV58045965; called by muse, mutect2, varscan2
- BCAS1 | c.457A>T p.T153S | Missense Mutation (SNP) | VAF 114/249 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.066); catalogued as COSV65087953, COSV65088509; called by muse, mutect2, varscan2
- BCLAF1 | c.778C>G p.Q260E | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs762271384, COSV62144100; called by muse, mutect2, varscan2
- BRINP2 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV100838259, COSV64178829; called by muse, mutect2, varscan2
- C12orf60 | c.700A>G p.M234V | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs1292831226, COSV57452651; called by muse, mutect2, varscan2
- CA10 | c.665T>C p.I222T | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.114); catalogued as rs766820678, COSV53360349; called by muse, mutect2, varscan2
- CACNA1D | c.2598C>G p.F866L (on ENST00000350061 / NM_001128840.3; = p.F886L on NM_000720.4) | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.084); catalogued as COSV55456335; called by muse, mutect2, varscan2
- CASP8 | c.698G>A p.R233Q (on ENST00000432109 / NM_033355.3; = p.R250Q on NM_001228.4) | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.787); catalogued as rs771150445, COSV51844924; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC63 | c.162G>T p.Q54H | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as COSV57529554; called by muse, mutect2, varscan2
- CDH22 | c.862G>C p.E288Q | Missense Mutation (SNP) | VAF 60/136 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV64838646; called by muse, mutect2, varscan2
- CDK6 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.77); PolyPhen probably damaging (0.999); catalogued as COSV56006230, COSV56010583; called by muse, mutect2, varscan2
- CEACAM21 | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.55); catalogued as COSV51814951; called by muse, mutect2, varscan2
- CNMD | c.653G>A p.R218K | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.089); catalogued as COSV65033599; called by muse, mutect2, varscan2
- COL2A1 | c.1262C>A p.S421Y | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV61532394, COSV61535539; called by muse, mutect2, varscan2
- COL2A1 | c.562G>C p.D188H | Missense Mutation (SNP) | VAF 136/602 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.67); catalogued as COSV61532398; called by muse, mutect2, varscan2
- COQ5 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs759921272, COSV56019771, COSV56020202; called by muse, mutect2, varscan2
- CUX2 | c.222+1G>T p.X74_splice | Splice Site (SNP) | VAF 66/140 reads (47%) | catalogued as COSV55640103; called by muse, mutect2, varscan2
- DARS2 | c.217C>A p.Q73K | Missense Mutation (SNP) | VAF 54/98 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53407926; called by muse, mutect2, varscan2
- DHRS7 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.043); catalogued as COSV53666926; called by muse, mutect2, varscan2
- DIP2B | c.538C>T p.Q180* | Nonsense Mutation (SNP) | VAF 88/161 reads (55%) | catalogued as COSV56591472; called by muse, mutect2, varscan2
- DMD | c.8196A>C p.K2732N | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV58930364; called by muse, mutect2, varscan2
- DNAH10 | c.3439G>A p.E1147K (on ENST00000409039; = p.E1086K on NM_207437.3) | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.021); catalogued as COSV68997340; called by muse, mutect2, varscan2
- DOCK4 | c.2209G>A p.E737K | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.621); catalogued as COSV70240270; called by muse, mutect2, varscan2
- DSG2 | c.404G>A p.R135K | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55200963; called by muse, mutect2, varscan2
- EFHC2 | c.923G>A p.G308D | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.241); catalogued as rs1301321956, COSV69554549; called by muse, mutect2, varscan2
- EMSY | c.3442G>C p.D1148H | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.819); catalogued as COSV58263521; called by muse, mutect2, varscan2
- ENTPD2 | c.707A>G p.Y236C | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57075995; called by muse, mutect2, varscan2
- EVL | c.770G>A p.R257Q (on ENST00000402714 / NM_001330221.2; = p.R259Q on NM_016337.3) | Missense Mutation (SNP) | VAF 48/71 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs566542060, COSV67376377; called by muse, mutect2, varscan2
- FAM120C | c.2287C>G p.L763V | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60260777; called by muse, mutect2, varscan2
- FBXW7 | c.502-1G>C p.X168_splice (on ENST00000281708 / NM_001349798.2; = p.X88_splice on NM_018315.5) | Splice Site (SNP) | VAF 8/14 reads (57%) | catalogued as COSV99656634, COSV99662518; called by muse, varscan2
- FPGT | c.1535C>A p.S512* | Nonsense Mutation (SNP) | VAF 51/111 reads (46%) | catalogued as COSV63836473; called by muse, mutect2, varscan2
- FRY | c.5366A>T p.D1789V | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as COSV66574389; called by muse, mutect2, varscan2
- G3BP2 | c.1355G>C p.R452T | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.916); catalogued as COSV62976952; called by muse, mutect2, varscan2
- GAD2 | c.1497T>C p.P499= | Splice Region (SNP) | VAF 134/447 reads (30%) | catalogued as COSV52162986; called by muse, mutect2, varscan2
- GDF11 | c.827C>T p.P276L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.036); catalogued as rs779013078, COSV57689229; called by muse, mutect2, varscan2
- GLUD2 | c.1469C>T p.T490M | Missense Mutation (SNP) | VAF 119/239 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as rs141237083, COSV60151504; called by muse, mutect2, varscan2
- GPR174 | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs764297256, COSV52133391; called by muse, mutect2, varscan2
- GPR45 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 114/163 reads (70%) | SIFT deleterious (0.02); PolyPhen benign (0.2); catalogued as COSV51525046, COSV99306565; called by muse, mutect2, varscan2
- GRIA2 | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 39/180 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV52398090; called by muse, mutect2, varscan2
- GRM7 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751709827, COSV63155421; called by muse, mutect2, varscan2
- GTPBP2 | c.396G>C p.E132D | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.054); catalogued as COSV61076001, COSV61076857; called by muse, mutect2, varscan2
- GUCY1A2 | c.2005G>C p.E669Q | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.904); catalogued as COSV56494027, COSV99974023; called by muse, mutect2, varscan2
- HCN1 | c.2459C>T p.T820M | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.067); catalogued as COSV57503237; called by muse, mutect2, varscan2
- HECTD4 | c.3281G>C p.R1094T | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV61180597; called by muse, mutect2, varscan2
- HELZ | c.3479G>C p.R1160T | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.702); catalogued as rs1567819106, COSV62379064, COSV62379677; called by muse, mutect2, varscan2
- HIP1 | c.644C>G p.T215R | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61183642; called by muse, mutect2
- HNMT | c.853C>G p.L285V | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV54509133; called by muse, mutect2, varscan2
- IFT122 | c.916C>G p.L306V (on ENST00000348417 / NM_052989.3; = p.L247V on NM_018262.4) | Missense Mutation (SNP) | VAF 78/154 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56205610, COSV56209159; called by muse, mutect2, varscan2
- IGSF10 | c.4097C>G p.S1366C | Missense Mutation (SNP) | VAF 74/320 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.436); catalogued as COSV56788605; called by muse, mutect2, varscan2
- IL26 | c.386G>C p.R129T | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV57489515; called by muse, mutect2, varscan2
- INTS9 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.492); catalogued as COSV68435146; called by muse, mutect2, varscan2
- IRF2BPL | c.1894G>C p.D632H | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53148063; called by muse, mutect2, varscan2
- JSRP1 | c.241G>C p.E81Q | Missense Mutation (SNP) | VAF 69/257 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV55559720; called by muse, mutect2, varscan2
- KCNG1 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 32/211 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.285); catalogued as COSV65369812; called by muse, mutect2, varscan2
- KCNH7 | c.1327G>C p.E443Q | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.027); catalogued as COSV59805037; called by muse, mutect2, varscan2
- KDM4D | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV58635485; called by muse, mutect2, varscan2
- KIF1A | c.1835C>T p.T612M | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); catalogued as rs760338913, COSV57495098; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KLHDC8A | c.865C>G p.Q289E | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.08); catalogued as COSV100903863, COSV65679077; called by muse, mutect2, varscan2
- KMT2D | c.16159C>T p.Q5387* | Nonsense Mutation (SNP) | VAF 48/86 reads (56%) | catalogued as COSV99980828; called by muse, mutect2, varscan2
- KRT78 | c.539G>T p.R180L | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV58851264; called by muse, mutect2, varscan2
- LDB2 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 71/155 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58775490, COSV58783722; called by muse, mutect2, varscan2
- LETMD1 | c.950T>C p.I317T | Missense Mutation (SNP) | VAF 21/110 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1406775046, COSV50398493; called by muse, mutect2, varscan2
- LRBA | c.3942G>A p.M1314I | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.022); catalogued as rs761765555, COSV63959813; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MALT1 | c.1053G>T p.M351I | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV61935673; called by muse, mutect2, varscan2
- MAN1A2 | c.307G>C p.E103Q | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.167); catalogued as COSV100740756, COSV62979701; called by muse, mutect2, varscan2
- MED12 | c.2247G>T p.E749D | Missense Mutation (SNP) | VAF 53/82 reads (65%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.999); catalogued as COSV61348062; called by muse, mutect2, varscan2
- MYH1 | c.4477G>C p.E1493Q | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV56848477, COSV56852899; called by muse, varscan2
- MYH1 | c.4408G>C p.E1470Q | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV56852909; called by muse, varscan2
- MYH7 | c.4741G>A p.E1581K | Missense Mutation (SNP) | VAF 57/465 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as COSV62521473; called by muse, mutect2, varscan2
- MYO18B | c.4339G>A p.A1447T | Missense Mutation (SNP) | VAF 73/100 reads (73%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.689); catalogued as COSV59141481; called by muse, mutect2, varscan2
- NAA25 | c.2632G>C p.E878Q | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV55708505; called by muse, mutect2
- NCOR2 | c.496C>T p.R166W | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs768616938, COSV62300871; called by muse, mutect2, varscan2
- NFE2L2 | c.1597A>C p.K533Q | Missense Mutation (SNP) | VAF 102/207 reads (49%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV67961715; called by muse, mutect2, varscan2
- NIN | c.2647G>C p.E883Q | Missense Mutation (SNP) | VAF 99/138 reads (72%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as COSV55398651; called by muse, mutect2, varscan2
- NLRP14 | c.2430A>C p.L810F | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs766563383, COSV55069720; called by muse, mutect2, varscan2
- NMD3 | c.152C>A p.S51* | Nonsense Mutation (SNP) | VAF 61/197 reads (31%) | catalogued as COSV63618920; called by muse, mutect2, varscan2
- NSFL1C | c.743G>A p.G248E | Missense Mutation (SNP) | VAF 155/510 reads (30%) | SIFT tolerated (0.99); PolyPhen benign (0.131); catalogued as COSV53794423; called by muse, varscan2
- NUP188 | c.487G>C p.D163H | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); catalogued as COSV65363455; called by muse, mutect2, varscan2
- OR5M10 | c.686G>T p.R229L | Missense Mutation (SNP) | VAF 64/128 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as COSV101595882; called by muse, mutect2, varscan2
- OTUD7A | c.1844G>A p.R615Q (on ENST00000307050 / NM_001382637.1; = p.R608Q on NM_130901.3) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0.003); catalogued as rs773844518; called by muse, mutect2, varscan2
- PCDH9 | c.802G>C p.G268R | Missense Mutation (SNP) | VAF 64/121 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60570081, COSV60573033; called by muse, mutect2, varscan2
- PCDHA7 | c.1282C>T p.R428W | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.605); catalogued as rs566217489, COSV65342591; called by muse, mutect2, varscan2
- PDE6B | c.1915G>A p.E639K | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV55328573; called by muse, mutect2, varscan2
- PDGFRA | c.1471G>A p.A491T | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.037); catalogued as rs563016888, COSV57265591, COSV99958005; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- PDLIM3 | c.366G>C p.Q122H (on ENST00000284770 / NM_001257963.1; = p.Q289H on NM_014476.6) | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.627); catalogued as COSV52980304; called by muse, mutect2, varscan2
- PGAP2 | c.262C>T p.R88C (on ENST00000463452 / NM_001346398.2; = p.R149C on NM_014489.4) | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs963222879, COSV53466083; called by muse, mutect2, varscan2
- PHF12 | c.314G>C p.R105P | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52020708, COSV52021407; called by muse, mutect2
- PLCD4 | c.2069G>A p.R690Q | Missense Mutation (SNP) | VAF 188/387 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs369131130; called by muse, mutect2, varscan2
- PLCE1 | c.5491G>A p.E1831K | Missense Mutation (SNP) | VAF 83/241 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53361016; called by muse, mutect2, varscan2
- PLEKHG7 | c.43G>C p.D15H | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.334); catalogued as COSV67338072; called by muse, varscan2
- PLEKHG7 | c.112G>C p.D38H | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV67338075; called by muse, varscan2
- POTEE | c.970C>G p.L324V | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.874); catalogued as COSV100387822, COSV100389307; called by mutect2, varscan2
- PPEF2 | c.2194G>A p.D732N | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs760711815, COSV54421456; called by muse, mutect2, varscan2
- PPM1K | c.223A>G p.I75V | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.437); catalogued as rs769407666, COSV55796792; called by muse, mutect2, varscan2
- PPP1R2 | c.432G>T p.R144S | Missense Mutation (SNP) | VAF 53/116 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60498125; called by muse, mutect2, varscan2
- PRKCG | c.1516G>A p.V506I | Missense Mutation (SNP) | VAF 476/770 reads (62%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs745537039, COSV54730319; called by muse, mutect2, varscan2
- PRSS12 | c.2564C>A p.S855Y | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.498); catalogued as COSV56608085; called by muse, mutect2, varscan2
- PRX | c.3787G>C p.E1263Q | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.154); catalogued as COSV52523414; called by muse, mutect2, varscan2
- PRX | c.2995G>C p.D999H | Missense Mutation (SNP) | VAF 33/182 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52531843; called by muse, varscan2
- PRX | c.2839G>A p.E947K | Missense Mutation (SNP) | VAF 56/316 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1238884281, COSV52531850; called by muse, varscan2
- PRX | c.2656G>C p.E886Q | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.014); catalogued as COSV52531859, COSV99398152; called by muse, mutect2, varscan2
- PSPC1 | c.1021G>C p.E341Q | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.693); catalogued as COSV58889418; called by muse, mutect2, varscan2
- PTPN13 | c.7423G>C p.E2475Q (on ENST00000411767 / NM_080683.3; = p.E2456Q on NM_006264.3) | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV57412159; called by muse, mutect2, varscan2
- PWWP3A | c.82T>G p.S28A (on ENST00000627377; = p.S27A on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.263); catalogued as COSV60903490; called by muse, mutect2, varscan2
- QSER1 | c.3680C>G p.S1227C (on ENST00000399302; = p.S1356C on NM_001076786.3) | Missense Mutation (SNP) | VAF 83/225 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV67901195; called by muse, mutect2, varscan2
- RAP1B | c.8A>G p.E3G | Missense Mutation (SNP) | VAF 598/628 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51669624; called by muse, mutect2, varscan2
- REG3G | c.384G>A p.M128I | Missense Mutation (SNP) | VAF 48/232 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as rs377578383; called by muse, mutect2, varscan2
- RNF123 | c.3505G>C p.E1169Q | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.04); catalogued as COSV57539143; called by muse, mutect2, varscan2
- RPL35A | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.323); catalogued as COSV54564038; called by muse, mutect2, varscan2
- SAFB2 | c.2377G>C p.D793H | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as COSV53043830; called by muse, mutect2, varscan2
- SAMD9 | c.2471G>C p.R824P | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV66076683; called by muse, mutect2, varscan2
- SEMA3C | c.2137C>T p.R713W | Missense Mutation (SNP) | VAF 41/219 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs199571544, COSV54851316, COSV54851529, COSV54851916; called by muse, mutect2, varscan2
- SETBP1 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.052); catalogued as COSV56321385, COSV56325917; called by muse, mutect2, varscan2
- SFMBT2 | c.2664C>G p.F888L | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV62813129; called by muse, mutect2, varscan2
- SLC25A26 | c.287C>T p.S96F | Missense Mutation (SNP) | VAF 42/157 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as COSV60916001; called by muse, mutect2, varscan2
- SLC25A27 | c.946G>C p.E316Q | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as COSV64928416; called by muse, mutect2, varscan2
- SLC26A3 | c.1108G>C p.D370H | Missense Mutation (SNP) | VAF 76/161 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV60641363; called by muse, mutect2, varscan2
- SLC6A20 | c.1006G>A p.V336M | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.02); catalogued as rs185440350, COSV62071975; called by muse, mutect2, varscan2
- SLTM | c.2390T>A p.V797D | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.312); catalogued as COSV65849669; called by muse, mutect2, varscan2
- SMARCC1 | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54380355; called by muse, mutect2, varscan2
- SSH3 | c.886-1G>T p.X296_splice | Splice Site (SNP) | VAF 45/156 reads (29%) | catalogued as COSV57385769; called by muse, mutect2, varscan2
- ST6GAL2 | c.241C>G p.P81A | Missense Mutation (SNP) | VAF 30/108 reads (28%) | PolyPhen benign (0.01); catalogued as COSV64530046, COSV64531712; called by muse, mutect2, varscan2
- STARD8 | c.1829C>T p.S610F | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52929408; called by muse, mutect2, varscan2
- STUB1 | c.331G>C p.D111H | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV50199969; called by muse, mutect2, varscan2
- STUB1 | c.796C>T p.H266Y | Missense Mutation (SNP) | VAF 68/150 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV50199970; called by muse, mutect2, varscan2
- SVEP1 | c.3874C>T p.R1292C | Missense Mutation (SNP) | VAF 34/51 reads (67%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.657); catalogued as rs762787283, COSV57041972; called by muse, varscan2
- TACC3 | c.1564G>C p.E522Q | Missense Mutation (SNP) | VAF 65/195 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.769); catalogued as COSV57606411; called by muse, mutect2, varscan2
- TAF1 | c.2402G>A p.R801Q (on ENST00000373790 / NM_138923.4; = p.R822Q on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 116/207 reads (56%) | SIFT tolerated (0.16); PolyPhen benign (0.19); catalogued as COSV52119533; called by muse, mutect2, varscan2
- TASP1 | c.881G>C p.G294A | Missense Mutation (SNP) | VAF 82/303 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61814342; called by muse, mutect2, varscan2
- TBC1D21 | c.961G>C p.E321Q | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.114); catalogued as COSV55995994; called by muse, mutect2, varscan2
- TEPP | c.776C>A p.S259Y (on ENST00000441824 / NM_199456.3; = p.S286Y on NM_199046.3) | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV52043865, COSV99333063; called by muse, mutect2
- TMEM132D | c.2161A>C p.T721P | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV67161309; called by muse, mutect2, varscan2
- TNRC6A | c.3791A>G p.Q1264R | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT tolerated (0.9); PolyPhen possibly damaging (0.45); catalogued as COSV100170097, COSV59367556; called by muse, mutect2, varscan2
- TPK1 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 34/192 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV63644150; called by muse, mutect2, varscan2
- TPO | c.2552C>T p.S851F | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV61094377; called by muse, mutect2
- TSPAN8 | c.574G>C p.E192Q | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as rs774229763, COSV56079423, COSV99922720; called by muse, varscan2
- TTN | c.42646A>G p.I14216V (on ENST00000591111; = p.I6792V on NM_003319.4) | Missense Mutation (SNP) | VAF 22/109 reads (20%) | PolyPhen benign (0.003); catalogued as rs748048957, COSV60195748; called by muse, mutect2, varscan2
- UBL4A | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 54/324 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV54835991; called by muse, mutect2, varscan2
- UBR5 | c.1777G>A p.E593K | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.162); catalogued as COSV55294032; called by muse, mutect2, varscan2
- UTP14A | c.1637C>G p.P546R | Missense Mutation (SNP) | VAF 170/339 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.239); catalogued as COSV64087422; called by muse, mutect2, varscan2
- UTP4 | c.1684G>C p.D562H | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as COSV58732711, COSV58733755; called by muse, mutect2, varscan2
- VLDLR | c.2564C>G p.S855C | Missense Mutation (SNP) | VAF 79/174 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV66078221; called by muse, mutect2, varscan2
- VPS13B | c.9223G>C p.E3075Q | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.343); catalogued as COSV62149865; called by muse, mutect2, varscan2
- VSIG10 | c.850G>C p.D284H | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.361); catalogued as rs773721726, COSV63653981; called by muse, mutect2, varscan2
- WTAP | c.467A>G p.K156R | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.74); PolyPhen benign (0.404); catalogued as COSV61610423; called by muse, mutect2
- XYLT1 | c.704G>C p.R235T | Missense Mutation (SNP) | VAF 68/313 reads (22%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); catalogued as COSV54490720; called by muse, mutect2, varscan2
- ZFC3H1 | c.19C>G p.P7A | Missense Mutation (SNP) | VAF 127/253 reads (50%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV57349446; called by muse, mutect2, varscan2
- ZNF184 | c.350C>T p.S117F | Missense Mutation (SNP) | VAF 46/172 reads (27%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV53004936; called by muse, mutect2, varscan2
- ZNF354B | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as COSV59366834; called by muse, mutect2, varscan2
- ZNF641 | c.445C>G p.L149V | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56391023; called by muse, mutect2, varscan2
- ZNF671 | c.584G>A p.G195E | Missense Mutation (SNP) | VAF 58/277 reads (21%) | SIFT tolerated (0.92); PolyPhen benign (0.005); catalogued as COSV58053664; called by muse, mutect2, varscan2
- ZNF677 | c.392G>A p.R131K | Missense Mutation (SNP) | VAF 47/170 reads (28%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.516); catalogued as COSV61720243, COSV61720872; called by muse, mutect2, varscan2
- AASDH | c.10C>T p.Q4* | Nonsense Mutation (SNP) | VAF 40/123 reads (33%) | called by muse, mutect2, varscan2
- AGFG2 | c.317_320del p.V106Afs*15 | Frame Shift Del (DEL) | VAF 159/273 reads (58%) | called by mutect2, pindel, varscan2
- AXIN1 | c.1828G>T p.E610* | Nonsense Mutation (SNP) | VAF 100/458 reads (22%) | called by muse, mutect2, varscan2
- CRYBA2 | c.15_29del p.A6_A10del | In Frame Del (DEL) | VAF 7/18 reads (39%) | called by mutect2, varscan2
- DPP9 | c.1432G>C p.E478Q (on ENST00000598800; = p.E507Q on NM_139159.5) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.251); called by muse, mutect2
- FLNC | c.5843-2_5850del p.X1948_splice | Splice Site (DEL) | VAF 26/222 reads (12%) | called by mutect2, pindel
- KLF5 | c.677dup p.H227Pfs*27 | Frame Shift Ins (INS) | VAF 22/105 reads (21%) | called by mutect2, pindel, varscan2
- MAGEC1 | c.2395C>T p.Q799* | Nonsense Mutation (SNP) | VAF 217/587 reads (37%) | called by muse, mutect2, varscan2
- MYO1F | c.2888G>C p.R963T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.029); called by muse, mutect2
- PSMD12 | c.964G>T p.E322* | Nonsense Mutation (SNP) | VAF 16/83 reads (19%) | called by muse, mutect2, varscan2
- PSME4 | c.1204C>T p.Q402* | Nonsense Mutation (SNP) | VAF 47/104 reads (45%) | called by muse, mutect2, varscan2
- RBP3 | c.3424C>G p.L1142V | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPAG7 | c.211C>T p.Q71* | Nonsense Mutation (SNP) | VAF 69/146 reads (47%) | called by muse, mutect2, varscan2
- ABCA8 | c.405T>C p.Y135= | Silent (SNP) | VAF 27/88 reads (31%) | catalogued as COSV52207041; called by muse, mutect2, varscan2
- ADAMTS1 | c.1158C>T p.S386= | Silent (SNP) | VAF 39/129 reads (30%) | catalogued as rs141975781, COSV53170387; called by muse, mutect2, varscan2
- ALB | c.1704G>A p.L568= | Silent (SNP) | VAF 29/139 reads (21%) | catalogued as rs11538206, COSV55740259; called by muse, mutect2, varscan2
- ALDH16A1 | c.2101C>T p.L701= | Silent (SNP) | VAF 16/360 reads (4%) | catalogued as COSV53195308; called by muse, mutect2
- AP3D1 | c.564G>A p.L188= | Silent (SNP) | VAF 32/110 reads (29%) | catalogued as COSV61425026; called by muse, mutect2, varscan2
- B4GALNT1 | c.1155G>A p.A385= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as rs771293936, COSV57542262; called by muse, mutect2, varscan2
- CELSR1 | c.5802C>T p.C1934= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs775270009, COSV53094770; called by muse, mutect2, varscan2
- CENPE | c.951T>G p.L317= | Silent (SNP) | VAF 29/180 reads (16%) | catalogued as COSV54384763; called by muse, mutect2, varscan2
- CLN6 | c.303C>T p.I101= | Silent (SNP) | VAF 22/105 reads (21%) | catalogued as rs1369226101, COSV51116690; ClinVar: likely benign; called by muse, mutect2
- CNOT3 | c.1710C>A p.I570= | Silent (SNP) | VAF 65/432 reads (15%) | catalogued as COSV55365821; called by muse, mutect2, varscan2
- COG1 | c.2022C>T p.L674= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV55430888; called by muse, mutect2, varscan2
- CORO2A | c.1395G>C p.L465= | Silent (SNP) | VAF 67/231 reads (29%) | catalogued as COSV59663921; called by muse, mutect2, varscan2
- DOT1L | c.1947G>A p.K649= | Silent (SNP) | VAF 36/124 reads (29%) | catalogued as COSV67111715; called by muse, varscan2
- ERCC6L2 | c.1587C>G p.L529= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as rs200839216, COSV56632544; called by muse, mutect2, varscan2
- FNBP1 | c.1704G>A p.T568= | Silent (SNP) | VAF 25/83 reads (30%) | catalogued as rs781328311, COSV63088976; called by muse, mutect2, varscan2
- FURIN | c.807C>T p.L269= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as rs146865309; called by muse, mutect2, varscan2
- HTR2C | c.1089C>T p.I363= | Silent (SNP) | VAF 145/308 reads (47%) | catalogued as COSV52218717; called by muse, mutect2, varscan2
- HUWE1 | c.5865A>G p.A1955= | Silent (SNP) | VAF 56/134 reads (42%) | catalogued as COSV53348040; called by muse, mutect2, varscan2
- KCNH5 | c.2010G>C p.L670= | Silent (SNP) | VAF 105/197 reads (53%) | catalogued as COSV59768194; called by muse, mutect2, varscan2
- KDM6A | c.3060C>T p.I1020= | Silent (SNP) | VAF 50/154 reads (32%) | catalogued as COSV65042984, COSV65043066; called by muse, mutect2, varscan2
- KLK14 | c.360C>T p.P120= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as rs767260497, COSV50069534; called by muse, mutect2, varscan2
- LRP1B | c.5038C>T p.L1680= | Silent (SNP) | VAF 49/116 reads (42%) | catalogued as COSV67249352; called by muse, mutect2, varscan2
- MED10 | c.45C>T p.F15= | Silent (SNP) | VAF 24/40 reads (60%) | catalogued as COSV55386384; called by muse, mutect2, varscan2
- NOTCH1 | c.6693C>G p.L2231= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV53072321, COSV99491511; called by muse, mutect2, varscan2
- OCA2 | c.1539C>T p.F513= | Silent (SNP) | VAF 23/44 reads (52%) | catalogued as COSV62351871; called by muse, mutect2, varscan2
- OR5M8 | c.663C>T p.F221= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as rs771221040, COSV59115724; called by muse, mutect2, varscan2
- OR6Y1 | c.918C>T p.L306= | Silent (SNP) | VAF 28/113 reads (25%) | catalogued as COSV56929631; called by muse, mutect2, varscan2
- PAQR8 | c.621C>T p.V207= | Silent (SNP) | VAF 51/107 reads (48%) | catalogued as rs956113620, COSV62442967; called by muse, mutect2, varscan2
- PC | c.1761C>G p.L587= | Silent (SNP) | VAF 49/172 reads (28%) | catalogued as COSV58922219; called by muse, mutect2, varscan2
- PCDHA13 | c.1671C>T p.D557= | Silent (SNP) | VAF 70/113 reads (62%) | catalogued as rs782266148, COSV56480434; called by muse, mutect2, varscan2
- PDE3A | c.825G>A p.L275= | Silent (SNP) | VAF 48/92 reads (52%) | catalogued as rs750288734, COSV62967221; called by muse, mutect2, varscan2
- PRSS23 | c.276C>T p.A92= | Silent (SNP) | VAF 28/79 reads (35%) | catalogued as rs1453447462, COSV54707203; called by muse, mutect2, varscan2
- PTPRB | c.5169C>G p.L1723= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV54247292; called by muse, mutect2, varscan2
- RNF121 | c.483C>T p.L161= | Silent (SNP) | VAF 63/169 reads (37%) | catalogued as COSV62317282; called by muse, mutect2, varscan2
- RXRA | c.489G>A p.V163= | Silent (SNP) | VAF 71/110 reads (65%) | catalogued as rs749580298, COSV62684808; called by muse, mutect2, varscan2
- SF3A1 | c.147C>G p.V49= | Silent (SNP) | VAF 31/210 reads (15%) | catalogued as COSV53170118; called by muse, mutect2, varscan2
- SNTG2 | c.771C>T p.L257= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs773958917, COSV57995845; called by muse, mutect2, varscan2
- SPANXN1 | c.159G>A p.A53= | Silent (SNP) | VAF 89/218 reads (41%) | catalogued as rs782807503, COSV65122958, COSV65123182; called by muse, mutect2, varscan2
- SZT2 | c.4374C>T p.F1458= (on ENST00000634258 / NM_001365999.1; = p.F1401= on NM_015284.4) | Silent (SNP) | VAF 163/222 reads (73%) | catalogued as COSV65171846, COSV65174228; called by muse, mutect2, varscan2
- TFF2 | c.303C>T p.C101= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as rs983611612, COSV52296758; called by muse, varscan2
- TG | c.2922G>A p.P974= | Silent (SNP) | VAF 34/207 reads (16%) | catalogued as rs748636258, COSV55083350; called by muse, mutect2, varscan2
- TJP1 | c.3162C>T p.L1054= | Silent (SNP) | VAF 141/637 reads (22%) | catalogued as rs759944079, COSV62040790; called by muse, mutect2, varscan2
- TLR2 | c.1491C>G p.L497= | Silent (SNP) | VAF 24/153 reads (16%) | catalogued as COSV52605146; called by muse, mutect2, varscan2
- TNPO2 | c.645C>T p.I215= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs762506991, COSV63509224; called by muse, mutect2, varscan2
- TRIM54 | c.78C>T p.C26= | Silent (SNP) | VAF 81/479 reads (17%) | catalogued as COSV56080753; called by muse, mutect2, varscan2
- VILL | c.837G>A p.Q279= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV52186486; called by mutect2, varscan2
- WNK4 | c.957C>T p.I319= | Silent (SNP) | VAF 74/304 reads (24%) | catalogued as COSV53821500; called by muse, mutect2, varscan2
- XPO6 | c.1662G>C p.L554= | Silent (SNP) | VAF 60/207 reads (29%) | catalogued as COSV100484756, COSV58968788; called by muse, mutect2, varscan2
- ZMIZ2 | c.63C>T p.F21= | Silent (SNP) | VAF 88/138 reads (64%) | catalogued as rs201213111, COSV54809143, COSV54809718; called by muse, mutect2, varscan2
- ZNF710 | c.1893C>T p.F631= | Silent (SNP) | VAF 46/190 reads (24%) | catalogued as rs200749761; called by muse, mutect2, varscan2
- CNOT3 | c.2037+201C>G | Intron (SNP) | VAF 11/59 reads (19%) | catalogued as COSV55365849; called by muse, mutect2, varscan2
- EPDR1 | c.-174C>T | 5'UTR (SNP) | VAF 40/57 reads (70%) | catalogued as COSV52259813; called by muse, mutect2, varscan2
- KAT6A | c.1483-1747G>T | Intron (SNP) | VAF 49/145 reads (34%) | catalogued as COSV55909138; called by muse, mutect2, varscan2
- NXF5 | n.1009G>A | RNA (SNP) | VAF 16/77 reads (21%) | catalogued as rs770836662; called by muse, varscan2
- PCDH11X | c.3033+3670G>A | Intron (SNP) | VAF 24/93 reads (26%) | catalogued as COSV53486661; called by muse, mutect2, varscan2
- TMPRSS11F | c.1015+2132G>A | Intron (SNP) | VAF 45/256 reads (18%) | catalogued as rs765118211, COSV100678503; called by muse, mutect2, varscan2
